CPTAC case C3N-01946 — Larynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/14b0b2d5-46a1-426c-aec2-9b6520f92347

Demographics
Sex at birth: male; Race: white; Year of birth: 1952; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Larynx, NOS; Age at diagnosis: 64.9 years (23,694 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,865 days (5.1 years); Progression or recurrence: no; Days to last follow up: 1,865 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.5 cm (a second GDC size field records 2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 1; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (6 entries)
- Days to follow up: 217 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 238 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 601 days (1.6 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 966 days (2.6 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,335 days (3.7 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,865 days (5.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 83 kg; Height: 176 cm; BMI: 26.79.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01946-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 218 mg; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01946-21: Section location: Larynx; Percent tumor nuclei: 90; Percent necrosis: 3.
- Sample C3N-01946-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 134 mg; Time between excision and freezing: 4 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01946-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
